Somatic mutation profile of tumor specimen TCGA-IB-7885-01A (aliquot TCGA-IB-7885-01A-11D-2154-08) from TCGA case TCGA-IB-7885, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 78.2 years (28,554 days).
Specimen TCGA-IB-7885-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66ac984e-7371-4b4f-8614-06258cd2d79d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7885-10A (Blood Derived Normal), aliquot TCGA-IB-7885-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13488acd-f80c-4d1c-b754-113b632c9037

The open-access MAF lists 44 somatic variants for this specimen: 28 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 15, Nonsense Mutation 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TPO | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140124953, CM035088; ClinVar: pathogenic; called by muse, mutect2
- ABCC9 | c.3160T>A p.S1054T | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.292); catalogued as COSV99687103; called by muse, mutect2
- AL645922.1 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs911687564, COSV100964060; called by muse, mutect2, varscan2
- CAPRIN1 | c.1228C>G p.P410A | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs771332542, COSV100404246; called by muse, mutect2
- EP300 | c.1721A>G p.D574G | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.842); catalogued as COSV99609728; called by muse, mutect2
- ETV3L | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 43/456 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs147712441; called by muse, mutect2
- FBXO15 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs144253482, COSV54044307; called by muse, mutect2
- HIPK3 | c.2915A>T p.D972V | Missense Mutation (SNP) | VAF 28/333 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV100306044; called by muse, mutect2
- KRBOX4 | c.454G>C p.A152P (on ENST00000344302 / NM_001129898.2; = p.A147P on NM_017776.2) | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV99994368; called by muse, mutect2
- MVB12B | c.663-1G>A p.X221_splice | Splice Site (SNP) | VAF 32/648 reads (5%) | catalogued as COSV100753140; called by muse, mutect2
- NGF | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs755243469, COSV65687836; called by muse, mutect2
- NRSN1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs199771455, COSV65893682, COSV65894498; called by muse, mutect2
- PACSIN3 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 34/431 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.37); catalogued as rs1442747406, COSV100096601; called by muse, mutect2
- PARD3B | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.527); catalogued as COSV100595112; called by muse, mutect2
- PCLO | c.5519A>G p.E1840G | Missense Mutation (SNP) | VAF 81/934 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100437491; called by muse, mutect2
- PLXNB3 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782461403, COSV100737898; called by muse, mutect2
- SEC16B | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV100381915; called by muse, mutect2
- SH2D4A | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs756706853, COSV56122830; called by muse, mutect2
- SLCO1C1 | c.219G>T p.R73S | Missense Mutation (SNP) | VAF 36/473 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56869117, COSV99859952; called by muse, mutect2
- SPTA1 | c.5775A>C p.E1925D | Missense Mutation (SNP) | VAF 48/752 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100935533; called by muse, mutect2
- TAF1 | c.4213A>G p.M1405V (on ENST00000373790 / NM_138923.4; = p.M1426V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99336926; called by muse, mutect2
- TBC1D32 | c.3676C>T p.R1226* | Nonsense Mutation (SNP) | VAF 40/381 reads (10%) | catalogued as rs1353651641, COSV51542788; called by muse, mutect2, varscan2
- TGFBR2 | c.229T>A p.C77S | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55449291, COSV99848090; called by muse, mutect2
- TRIM26 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as COSV68963507; called by muse, mutect2, varscan2
- TXNDC15 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 44/629 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs139088311; called by muse, mutect2
- ZFP91 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as rs769563604, COSV100284749; called by muse, mutect2
- ZNF292 | c.6589C>A p.H2197N | Missense Mutation (SNP) | VAF 62/900 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100371174, COSV60536366; called by muse, mutect2
- ZSWIM3 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1382156062, COSV54845151, COSV99667083; called by muse, mutect2
- ACAN | c.954C>T p.C318= | Silent (SNP) | VAF 11/212 reads (5%) | catalogued as rs1458616144, COSV100719210, COSV61371931; called by muse, mutect2
- BTNL9 | c.351C>T p.V117= | Silent (SNP) | VAF 14/240 reads (6%) | catalogued as COSV59798242; called by muse, mutect2
- ENDOD1 | c.966G>A p.E322= | Silent (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- FCER1A | c.210T>A p.L70= | Silent (SNP) | VAF 39/405 reads (10%) | catalogued as COSV100929306; called by muse, mutect2
- GPRIN1 | c.1500G>A p.L500= | Silent (SNP) | VAF 31/656 reads (5%) | catalogued as rs756062803, COSV56138072; called by muse, mutect2
- HECW1 | c.711A>G p.K237= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as COSV101224258; called by muse, mutect2
- HR | c.822G>A p.V274= | Silent (SNP) | VAF 46/620 reads (7%) | catalogued as COSV100456025; called by muse, mutect2
- IRAG1 | c.1377C>A p.I459= | Silent (SNP) | VAF 16/236 reads (7%) | catalogued as COSV101351682; called by muse, mutect2
- MYO7A | c.5826A>G p.G1942= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV68688199; called by muse, mutect2
- NCAM1 | c.1911C>T p.D637= (on ENST00000316851 / NM_181351.5; = p.D627= on NM_000615.7) | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as rs782154158, COSV57523655; called by muse, mutect2
- NIN | c.75A>C p.T25= | Silent (SNP) | VAF 120/1342 reads (9%) | catalogued as COSV99815153; called by muse, mutect2
- PRUNE2 | c.1344C>T p.D448= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as rs764714713, COSV65037698; called by muse, mutect2
- PSMC2 | c.210T>C p.T70= | Silent (SNP) | VAF 15/209 reads (7%) | catalogued as rs1343269874, COSV99485448; called by muse, mutect2
- THEMIS | c.1146C>T p.S382= | Silent (SNP) | VAF 39/373 reads (10%) | catalogued as rs1180503642, COSV64072401, COSV64072792; called by muse, mutect2, varscan2
- TLN1 | c.6987G>A p.R2329= | Silent (SNP) | VAF 28/290 reads (10%) | catalogued as COSV100148218; called by muse, mutect2, varscan2
- SSPOP | n.15213G>A | RNA (SNP) | VAF 17/234 reads (7%) | catalogued as COSV100948008; called by muse, mutect2
